Somatic mutation profile of tumor specimen TCGA-06-0155-01B (aliquot TCGA-06-0155-01B-01D-1492-08) from TCGA case TCGA-06-0155, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 61.6 years (22,498 days).
Specimen TCGA-06-0155-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 875e0b56-4274-4ce8-b792-ff4289b9f191.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-06-0155-10A (Blood Derived Normal), aliquot TCGA-06-0155-10A-01D-1492-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bf03b827-8f2e-4e3b-a8e9-c39c549ae2a7

The open-access MAF lists 73 somatic variants for this specimen: 53 protein-altering or splice-affecting, 18 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 47, Silent 18, Nonsense Mutation 3, RNA 2, In Frame Del 1, Frame Shift Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.910C>T p.H304Y | Missense Mutation (SNP) | VAF 117/511 reads (23%) | hotspot (GDC flag); SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV51765787; called by muse, mutect2, varscan2
- PTEN | c.406T>C p.C136R | Missense Mutation (SNP) | VAF 110/165 reads (67%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs786201044, CM004336, COSV100911109, COSV64289087; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ANGPTL1 | c.541T>C p.S181P | Missense Mutation (SNP) | VAF 46/137 reads (34%) | SIFT tolerated (0.25); PolyPhen benign (0.122); catalogued as COSV52365636; called by muse, mutect2, varscan2
- AP4B1 | c.1643C>T p.P548L | Missense Mutation (SNP) | VAF 45/117 reads (38%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs149723440; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ASPSCR1 | c.461C>T p.T154M | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs372730667; called by muse, mutect2, varscan2
- ATAD2 | c.2389A>G p.I797V | Missense Mutation (SNP) | VAF 75/185 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.1); catalogued as COSV54878117; called by muse, mutect2, varscan2
- BMP3 | c.827A>G p.H276R | Missense Mutation (SNP) | VAF 44/149 reads (30%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as COSV51081939; called by muse, mutect2, varscan2
- CAPN13 | c.1325G>A p.R442H | Missense Mutation (SNP) | VAF 130/324 reads (40%) | SIFT tolerated (0.13); PolyPhen benign (0.012); catalogued as rs771712940, COSV54428881; called by muse, mutect2, varscan2
- CARD6 | c.2345G>A p.S782N | Missense Mutation (SNP) | VAF 173/469 reads (37%) | SIFT tolerated (0.43); PolyPhen benign (0.001); catalogued as COSV54564637; called by muse, mutect2, varscan2
- CD44 | c.1660A>G p.T554A | Missense Mutation (SNP) | VAF 114/299 reads (38%) | SIFT tolerated (0.33); PolyPhen benign (0.007); catalogued as rs1268940899, COSV53528403; called by muse, mutect2, varscan2
- CES4A | c.1516G>A p.G506R (on ENST00000648724 / NM_001364782.1; = p.G408R on NM_001190201.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 67/154 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100110182, COSV58652147; called by muse, mutect2, varscan2
- CHRM3 | c.1484C>T p.A495V | Missense Mutation (SNP) | VAF 87/223 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs903730617, COSV55082398; called by muse, mutect2, varscan2
- COG6 | c.1562G>A p.R521H | Missense Mutation (SNP) | VAF 56/180 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.184); catalogued as rs780630711, COSV62995228; called by muse, mutect2, varscan2
- DCAF12L2 | c.737G>A p.R246H | Missense Mutation (SNP) | VAF 30/44 reads (68%) | SIFT tolerated (0.52); PolyPhen benign (0.379); catalogued as COSV63580194; called by muse, mutect2, varscan2
- DSCAM | c.3377T>A p.V1126D | Missense Mutation (SNP) | VAF 58/202 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); catalogued as COSV101258967, COSV68022293; called by muse, mutect2, varscan2
- DYSF | c.4427A>C p.D1476A | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50274726; called by muse, mutect2, varscan2
- FANCM | c.4699A>G p.K1567E | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.556); catalogued as rs1312455073, COSV57498011; called by muse, mutect2, varscan2
- FGL1 | c.647C>T p.A216V | Missense Mutation (SNP) | VAF 15/229 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0.137); catalogued as rs766665979, COSV67711991; called by muse, mutect2
- FRA10AC1 | c.70A>G p.K24E | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.024); catalogued as COSV63271090; called by muse, varscan2
- GLP1R | c.118C>T p.R40* | Nonsense Mutation (SNP) | VAF 26/75 reads (35%) | catalogued as rs141990898; called by muse, mutect2, varscan2
- GPR37 | c.104G>C p.R35T | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.035); catalogued as COSV58255747; called by muse, mutect2, varscan2
- HNRNPA2B1 | c.612_613+1del p.X204_splice (on ENST00000354667 / NM_031243.3; = p.X192_splice on NM_002137.4) | Splice Site (DEL) | VAF 121/550 reads (22%) | catalogued as rs902316320; called by pindel, varscan2
- ITPR3 | c.5720C>T p.T1907M | Missense Mutation (SNP) | VAF 24/77 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1277690994, COSV65406512; called by muse, mutect2, varscan2
- LHX5 | c.727G>A p.A243T | Missense Mutation (SNP) | VAF 3/21 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.014); catalogued as COSV55662098; called by muse, mutect2
- LMAN1 | c.304G>T p.E102* | Nonsense Mutation (SNP) | VAF 67/180 reads (37%) | catalogued as COSV51826091; called by muse, mutect2, varscan2
- MIB1 | c.277A>G p.I93V | Missense Mutation (SNP) | VAF 86/210 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.391); catalogued as rs777278397, COSV55088402; called by muse, mutect2, varscan2
- MMP21 | c.1354G>C p.D452H | Missense Mutation (SNP) | VAF 83/138 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV61762664; called by muse, mutect2, varscan2
- MYF5 | c.386G>A p.R129H | Missense Mutation (SNP) | VAF 77/221 reads (35%) | SIFT tolerated (0.05); PolyPhen benign (0.094); catalogued as rs893795100, COSV57354577; called by muse, mutect2, varscan2
- OBSCN | c.3191G>T p.R1064L | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT tolerated (0.15); PolyPhen benign (0.179); catalogued as rs553600555, COSV52748524; called by muse, mutect2, varscan2
- OR10H4 | c.485C>T p.T162M | Missense Mutation (SNP) | VAF 120/456 reads (26%) | SIFT tolerated (0.17); PolyPhen benign (0.01); catalogued as rs749272961, COSV59061323; called by muse, mutect2, varscan2
- OR52E6 | c.526A>C p.I176L | Missense Mutation (SNP) | VAF 99/244 reads (41%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.702); catalogued as COSV61431498; called by muse, mutect2, varscan2
- PPP3CB | c.1318A>T p.M440L | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV61151142; called by muse, mutect2, varscan2
- PRKCQ | c.235G>A p.V79M | Missense Mutation (SNP) | VAF 101/170 reads (59%) | SIFT tolerated (0.12); PolyPhen benign (0.006); catalogued as rs148376969, COSV54117893; called by muse, mutect2, varscan2
- QKI | c.335A>C p.Q112P | Missense Mutation (SNP) | VAF 58/141 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV51690227; called by muse, mutect2, varscan2
- QRFPR | c.622C>T p.P208S | Missense Mutation (SNP) | VAF 67/178 reads (38%) | SIFT tolerated (0.4); PolyPhen benign (0.046); catalogued as COSV57675548; called by muse, mutect2, varscan2
- RBL1 | c.2099A>T p.Q700L | Missense Mutation (SNP) | VAF 78/234 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.266); catalogued as COSV60328700; called by muse, mutect2, varscan2
- RCN3 | c.674A>G p.Y225C | Missense Mutation (SNP) | VAF 8/128 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54541337, COSV54542216; called by muse, mutect2
- SCN9A | c.4054A>T p.N1352Y (on ENST00000303354; = p.N1341Y on NM_002977.3) | Missense Mutation (SNP) | VAF 187/519 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57602547; called by muse, mutect2, varscan2
- SCNN1G | c.1691G>A p.R564H | Missense Mutation (SNP) | VAF 66/174 reads (38%) | SIFT tolerated (0.57); PolyPhen benign (0.001); catalogued as rs762732326, COSV55597490; called by muse, mutect2, varscan2
- SGCD | c.224G>T p.G75V (on ENST00000435422 / NM_001128209.2; = p.G76V on NM_000337.5) | Missense Mutation (SNP) | VAF 24/61 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61905125; called by muse, mutect2, varscan2
- SLC22A9 | c.1070C>T p.T357M | Missense Mutation (SNP) | VAF 106/286 reads (37%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs141060614; called by muse, mutect2, varscan2
- SLITRK4 | c.611G>A p.R204H | Missense Mutation (SNP) | VAF 99/172 reads (58%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.953); catalogued as rs1166723245, COSV62022486, COSV62023994, COSV62025718; called by muse, mutect2, varscan2
- SRPK2 | c.1324C>T p.R442* | Nonsense Mutation (SNP) | VAF 122/425 reads (29%) | catalogued as rs1437515182, COSV61959637; called by muse, mutect2, varscan2
- STAB1 | c.5729G>A p.R1910H | Missense Mutation (SNP) | VAF 31/524 reads (6%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as rs757142553, COSV58733082, COSV58742914; called by muse, mutect2
- STAB2 | c.3549G>T p.E1183D | Missense Mutation (SNP) | VAF 47/127 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.13); catalogued as COSV66335487; called by muse, mutect2, varscan2
- STK3 | c.676C>G p.P226A | Missense Mutation (SNP) | VAF 48/116 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.829); catalogued as COSV69222087, COSV69223584; called by muse, mutect2, varscan2
- SULT1B1 | c.658A>C p.I220L | Missense Mutation (SNP) | VAF 35/101 reads (35%) | SIFT tolerated (0.39); PolyPhen benign (0.007); catalogued as COSV60206815; called by muse, mutect2, varscan2
- TBPL2 | c.91C>T p.R31W | Missense Mutation (SNP) | VAF 53/124 reads (43%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as rs779730706, COSV55972049; called by muse, mutect2, varscan2
- TPST1 | c.890G>A p.G297E | Missense Mutation (SNP) | VAF 45/177 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV59175287; called by muse, mutect2, varscan2
- TTN | c.68878A>G p.I22960V (on ENST00000591111; = p.I15536V on NM_003319.4) | Missense Mutation (SNP) | VAF 41/105 reads (39%) | PolyPhen benign (0); catalogued as COSV59919415; called by muse, mutect2, varscan2
- ZIC1 | c.1046G>A p.R349H | Missense Mutation (SNP) | VAF 29/119 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV51551496; called by muse, mutect2, varscan2
- HNRNPU | c.968_970del p.D323del (on ENST00000283179; = p.D385del on NM_004501.3) | In Frame Del (DEL) | VAF 22/96 reads (23%) | called by pindel, varscan2
- PCDHGC3 | c.2088_2091del p.S697* | Frame Shift Del (DEL) | VAF 242/707 reads (34%) | called by pindel, varscan2
- ADAMTS6 | c.213G>A p.R71= | Silent (SNP) | VAF 71/214 reads (33%) | catalogued as COSV66857502; called by muse, mutect2, varscan2
- CACNA1C | c.639A>G p.E213= | Silent (SNP) | VAF 81/240 reads (34%) | catalogued as COSV59701439, COSV59709451; called by muse, varscan2
- CD209 | c.1212G>A p.A404= | Silent (SNP) | VAF 86/329 reads (26%) | catalogued as rs373806865; called by muse, mutect2, varscan2
- CDHR4 | c.423G>A p.V141= | Silent (SNP) | VAF 22/43 reads (51%) | catalogued as COSV58525848; called by muse, mutect2, varscan2
- CLCNKB | c.1467C>T p.F489= | Silent (SNP) | VAF 25/111 reads (23%) | catalogued as rs535003549, COSV65159859; called by muse, mutect2, varscan2
- DST | c.1443T>C p.S481= (on ENST00000361203 / NM_001374722.1; = p.S155= on NM_001723.6) | Silent (SNP) | VAF 73/220 reads (33%) | catalogued as COSV55001219; called by muse, mutect2, varscan2
- EHD4 | c.1407C>T p.N469= | Silent (SNP) | VAF 31/102 reads (30%) | catalogued as rs201800565, COSV55003288; called by muse, mutect2, varscan2
- FLT4 | c.1893G>A p.A631= | Silent (SNP) | VAF 18/47 reads (38%) | catalogued as rs1342889809, COSV56100693; called by muse, mutect2, varscan2
- HSF2 | c.1008C>A p.T336= | Silent (SNP) | VAF 63/164 reads (38%) | catalogued as COSV63773486; called by muse, mutect2, varscan2
- IL2RB | c.918G>A p.S306= | Silent (SNP) | VAF 33/75 reads (44%) | catalogued as rs751701712, COSV53425227; called by muse, mutect2, varscan2
- MAP1B | c.4887A>G p.A1629= | Silent (SNP) | VAF 60/229 reads (26%) | catalogued as COSV57095000; called by muse, mutect2, varscan2
- PRDM15 | c.2757C>T p.H919= | Silent (SNP) | VAF 9/34 reads (26%) | catalogued as rs201676459, COSV54149716; called by muse, mutect2, varscan2
- RAB11FIP3 | c.1380G>A p.E460= | Silent (SNP) | VAF 33/113 reads (29%) | catalogued as COSV51931004; called by muse, mutect2, varscan2
- SIGLEC11 | c.1962C>A p.L654= | Silent (SNP) | VAF 37/124 reads (30%) | catalogued as COSV68567529; called by muse, mutect2, varscan2
- SPATC1 | c.795G>A p.S265= | Silent (SNP) | VAF 74/198 reads (37%) | catalogued as rs782622347, COSV66298203; called by muse, mutect2, varscan2
- TPH2 | c.639T>A p.T213= | Silent (SNP) | VAF 234/611 reads (38%) | catalogued as COSV61590867; called by muse, mutect2, varscan2
- TUBB4A | c.48C>A p.I16= | Silent (SNP) | VAF 5/13 reads (38%) | catalogued as COSV51152462; called by muse, mutect2
- USP6NL | c.1659C>T p.N553= | Silent (SNP) | VAF 68/90 reads (76%) | catalogued as rs779869414, COSV53209607; called by muse, mutect2, varscan2
- EI24P4 | n.933C>T | RNA (SNP) | VAF 221/793 reads (28%) | catalogued as rs752601163; called by muse, mutect2, varscan2
- KIR3DX1 | n.898T>C | RNA (SNP) | VAF 79/318 reads (25%) | catalogued as COSV55597179; called by muse, mutect2, varscan2
